Somatic mutation profile of tumor specimen TCGA-2H-A9GQ-01A (aliquot TCGA-2H-A9GQ-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 80.8 years (29,497 days).
Specimen TCGA-2H-A9GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07078213-3fe8-4362-938e-a91cf2f49a26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GQ-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GQ-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8be65f60-94f6-425b-b717-f33b443ddd10

The open-access MAF lists 145 somatic variants for this specimen: 94 protein-altering or splice-affecting, 44 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 44, Frame Shift Del 6, Nonsense Mutation 4, Intron 4, RNA 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457_457+7del p.X153_splice | Splice Site (DEL) | VAF 17/25 reads (68%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- F2 | c.1814_1815del p.H605Rfs*13 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs776618390; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 29/39 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115896366; called by muse, mutect2, varscan2
- ACOT9 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV60537836; called by muse, mutect2, varscan2
- ARFGEF3 | c.6476G>A p.R2159H | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111914596; called by muse, mutect2, varscan2
- ASXL3 | c.5191C>A p.P1731T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV52482926; called by muse, mutect2, varscan2
- ATG2A | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs140600460; called by muse, mutect2, varscan2
- BIRC6 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV101429067; called by muse, mutect2, varscan2
- BPIFB2 | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs762816818; called by muse, mutect2, varscan2
- BTRC | c.811C>T p.L271F (on ENST00000370187 / NM_033637.4; = p.L235F on NM_003939.5) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs751086036; called by muse, mutect2, varscan2
- C1QTNF3 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99180740; called by muse, mutect2, varscan2
- CCL22 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 102/169 reads (60%) | catalogued as rs200292277; called by muse, mutect2, varscan2
- CD226 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs745995433, COSV99711590; called by muse, mutect2, varscan2
- CDCP2 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 185/321 reads (58%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV61282470; called by muse, varscan2
- CHORDC1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100272025; called by muse, mutect2, varscan2
- CRACD | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1282697985, COSV99949037; called by muse, mutect2, varscan2
- CYP2J2 | c.456G>C p.K152N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV64606001; called by muse, mutect2, varscan2
- DPP9 | c.2536G>A p.E846K (on ENST00000598800; = p.E875K on NM_139159.5) | Missense Mutation (SNP) | VAF 85/93 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1351575585; called by muse, mutect2, varscan2
- ESYT1 | c.574C>A p.R192S | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs773027543, COSV57277147; called by muse, mutect2, varscan2
- FLG | c.1696A>C p.S566R | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100911835; called by muse, mutect2, varscan2
- FRY | c.8135A>T p.K2712M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV66572434; called by muse, mutect2, varscan2
- GAPVD1 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144122272, COSV52927016; called by muse, mutect2, varscan2
- H4C5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63486069; called by muse, mutect2, varscan2
- HIBCH | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1049796593, COSV100675966; called by muse, mutect2, varscan2
- HRG | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs374953969, COSV51645079, COSV51647425; called by muse, mutect2, varscan2
- ITGA8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs748005596, COSV65229891; called by muse, mutect2, varscan2
- KPNA1 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs772368222; called by muse, mutect2, varscan2
- LAMA5 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs865915874, COSV53370656; called by muse, mutect2, varscan2
- MTMR3 | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100071535; called by muse, mutect2, varscan2
- NR1D1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1259886278, COSV99225311; called by muse, mutect2, varscan2
- OR4Q3 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59180477; called by muse, mutect2, varscan2
- PIK3CD | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV100740205; called by muse, mutect2, varscan2
- PPP2R2D | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs76274320; called by muse, mutect2, varscan2
- SEC24C | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs777799286, COSV100226415; called by muse, mutect2, varscan2
- SETDB2 | c.89A>T p.N30I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99321132; called by muse, mutect2, varscan2
- SH3TC2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as rs138040787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC39A7 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.669); catalogued as rs1562434351; called by muse, mutect2, varscan2
- SPATA31D1 | c.2804T>C p.L935P | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs1225397207; called by muse, mutect2, varscan2
- STK17B | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV55827463; called by muse, mutect2, varscan2
- TAGAP | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1389256068; called by muse, mutect2, varscan2
- USP34 | c.4998G>C p.E1666D | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.834); catalogued as COSV68405359; called by muse, mutect2, varscan2
- VCAN | c.2380A>C p.S794R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs772576243; called by muse, mutect2, varscan2
- AHCTF1 | c.2975A>G p.H992R (on ENST00000366508; = p.H966R on NM_015446.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMOTL2 | c.1667A>G p.E556G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD50 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARPP21 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ARRDC4 | c.35del p.G12Vfs*6 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- CASP1 | c.227T>G p.I76S | Missense Mutation (SNP) | VAF 94/178 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPE | c.1433C>G p.T478R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CSMD1 | c.9910del p.H3304Ifs*19 (on ENST00000520002; = p.H3303Ifs*19 on NM_033225.6) | Frame Shift Del (DEL) | VAF 42/95 reads (44%) | called by mutect2, pindel, varscan2
- CYLD | c.2403A>C p.E801D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DOCK10 | c.3539A>G p.K1180R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ETAA1 | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FUT9 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLB1L3 | c.1034C>G p.T345S | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GPT2 | c.1087del p.I363Sfs*6 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- HDAC1 | c.1424_1432del p.V475_E477del | In Frame Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, varscan2
- IGHV1OR21-1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 111/218 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- IPP | c.1538G>A p.W513* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KRTAP26-1 | c.509C>G p.A170G | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- LONP2 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARK3 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MTNR1B | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MUC6 | c.6425_6428del p.S2142Ffs*33 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- NAV3 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NFASC | c.3226C>G p.R1076G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NR0B1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- NRXN1 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- NUP107 | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAK1IP1 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2G | c.2279C>G p.S760C (on ENST00000676171; = p.S719C on NM_004570.5) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PIP4K2B | c.1189A>T p.T397S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLCB4 | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PPP1R7 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RASA1 | c.206dup p.E70Rfs*42 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- RBL1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- ROR2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SIRT3 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOGA1 | c.3662A>G p.D1221G | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- SRCAP | c.8168_8169del p.R2723Hfs*4 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4576T>G p.L1526V (on ENST00000367255 / NM_182961.4; = p.L1533V on NM_033071.3) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- TAF2 | c.2048A>C p.D683A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TBC1D9 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSHR | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UCP3 | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- UGT1A6 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- USP33 | c.560T>G p.L187W | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP34 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- XIRP2 | c.6721A>T p.T2241S (on ENST00000628543; = p.T2416S on NM_152381.6) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC5 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF148 | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF169 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ABCC8 | c.672G>A p.L224= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- ACAN | c.2295C>T p.G765= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs546447132, COSV61363420; called by muse, mutect2, varscan2
- ADGRF3 | c.1386G>A p.R462= (on ENST00000311519 / NM_001145168.1; = p.R263= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- ADGRG1 | c.1224C>T p.Y408= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs752398657, COSV65635413; called by muse, mutect2, varscan2
- ANGPT4 | c.1389C>T p.N463= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs375636235; called by muse, mutect2, varscan2
- CCDC63 | c.243A>G p.K81= | Silent (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- CELSR3 | c.2637C>T p.V879= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CHD9 | c.5721G>A p.V1907= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1049523821; called by muse, mutect2, varscan2
- COL3A1 | c.3024T>A p.G1008= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- CPZ | c.642G>A p.G214= (on ENST00000360986 / NM_001014447.3; = p.G203= on NM_003652.3) | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1317183138; called by muse, mutect2, varscan2
- CSF2RA | c.351G>A p.E117= | Silent (SNP) | VAF 58/70 reads (83%) | catalogued as COSV62625012; called by muse, mutect2, varscan2
- CSNK1A1L | c.660G>A p.P220= | Silent (SNP) | VAF 73/105 reads (70%) | catalogued as rs1479472478, COSV65790401; called by muse, mutect2, varscan2
- DLGAP2 | c.1086C>T p.D362= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs758718171, COSV70099024; called by muse, mutect2, varscan2
- DPP7 | c.840C>T p.F280= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs772636240; called by muse, mutect2, varscan2
- EIF5B | c.414T>C p.D138= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
- ERVFRD-1 | c.1524C>G p.T508= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- ESYT3 | c.2154C>A p.P718= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- FES | c.459G>A p.K153= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- GK2 | c.213G>A p.T71= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs777052519, COSV62626768, COSV62628190; called by muse, mutect2, varscan2
- GRK4 | c.1101C>T p.P367= (on ENST00000398052 / NM_182982.3; = p.P335= on NM_005307.3) | Silent (SNP) | VAF 62/72 reads (86%) | catalogued as rs147908042; called by muse, mutect2, varscan2
- LYN | c.936G>A p.E312= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- MAGEH1 | c.528C>T p.V176= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV61679076; called by muse, mutect2, varscan2
- MEF2C | c.1260T>A p.P420= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1179704373; called by muse, mutect2, varscan2
- MMP14 | c.54C>A p.L18= | Silent (SNP) | VAF 80/159 reads (50%) | catalogued as COSV100313974, COSV61289296; called by muse, mutect2, varscan2
- MUC6 | c.540C>T p.D180= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs777400951; called by muse, mutect2, varscan2
- MYRF | c.1302C>T p.H434= (on ENST00000278836 / NM_001127392.3; = p.H425= on NM_013279.4) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs370594037; called by muse, mutect2, varscan2
- NFATC2 | c.609G>A p.P203= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as rs765804863, COSV65353087; called by muse, mutect2, varscan2
- NOP14 | c.540C>T p.G180= | Silent (SNP) | VAF 44/51 reads (86%) | catalogued as rs1178322441, COSV58628296; called by muse, mutect2, varscan2
- NUTM2F | c.1146G>A p.A382= | Silent (SNP) | VAF 266/477 reads (56%) | catalogued as rs397839742; called by muse, mutect2, varscan2
- PCDH17 | c.3237G>T p.L1079= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1473586508, COSV64973658; called by muse, mutect2, varscan2
- PCDHA3 | c.1410G>A p.P470= | Silent (SNP) | VAF 91/237 reads (38%) | catalogued as rs782607988, COSV63538591; called by muse, mutect2, varscan2
- PCDHGC3 | c.828C>T p.N276= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1360022622, COSV99343190; called by muse, mutect2, varscan2
- PNLIPRP1 | c.54A>G p.K18= | Silent (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- PPFIA2 | c.3773G>A p.*1258= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- PRKDC | c.408G>A p.Q136= | Silent (SNP) | VAF 57/150 reads (38%) | catalogued as rs1337436941; called by muse, mutect2, varscan2
- PRRC2C | c.222T>C p.P74= (on ENST00000367742; = p.P72= on NM_015172.4) | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- RAB11B | c.606C>T p.P202= | Silent (SNP) | VAF 85/105 reads (81%) | called by muse, mutect2, varscan2
- RECQL5 | c.1572A>G p.E524= | Silent (SNP) | VAF 85/95 reads (89%) | called by muse, mutect2, varscan2
- RFX3 | c.1374C>T p.A458= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs1490026304; called by muse, mutect2, varscan2
- SYNE1 | c.5115A>G p.E1705= (on ENST00000367255 / NM_182961.4; = p.E1712= on NM_033071.3) | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV55101516; called by muse, mutect2, varscan2
- TBC1D21 | c.450C>T p.L150= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100311201; called by muse, mutect2, varscan2
- TNKS1BP1 | c.741C>T p.S247= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs773632907, COSV100836325; called by muse, mutect2, varscan2
- WNT10A | c.354T>C p.Y118= | Silent (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
- ZNF697 | c.1146C>T p.G382= | Silent (SNP) | VAF 34/42 reads (81%) | called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288135C>G | Intron (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3342+4587G>A | Intron (SNP) | VAF 27/31 reads (87%) | catalogued as COSV54849441; called by muse, mutect2, varscan2
- B4GALNT1 | c.*2707C>T | 3'UTR (SNP) | VAF 35/43 reads (81%) | catalogued as rs369961371; called by muse, mutect2, varscan2
- SNORD115-10 | n.8T>G | RNA (SNP) | VAF 81/151 reads (54%) | called by muse, mutect2, varscan2
- SNORD115-12 | n.9G>T | RNA (SNP) | VAF 65/113 reads (58%) | catalogued as rs927115557; called by muse, mutect2, varscan2
- TENM4 | c.-321+38409C>T | Intron (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- TGFBR2 | c.94+16276C>T | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
